Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MJ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MJ-06A (Metastatic).

[page 1 of 2]
PathNet History Upload External
Client

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to: N/A

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

CLINICAL NOTES

SPECIMEN INFORMATION

(L) axillary dissection.

MACROSCOPIC DESCRIPTION

"Left axillary clearance". An unorientated piece of fat with some skeletal muscle measuring 220 x 170 x 40mm containing multiple lymph nodes. Included with this is also a red top container, containing a separate lymph node.

- A. Largest node with metastatic tumour.
- B. 72 nodes.
- C. 2 nodes.
- D. 3 nodes.
- E. 4 nodes.
- F. 2 nodes.
- G. 1 node.
- H. 3 nodes.
- J. Benign lymph node in red top container.

Embedded whole.

1CD-0-3

Melanoma, NOS 8720/3

Site: lymph node, axillary

c 77.3

lw

8/24/11

MICROSCOPIC REPORT

"(L) axillary clearance". Sections show lymph nodes and adjacent adipose tissue. Deposits of pleomorphic spindle shaped cells that include areas of necrosis consistent with metastatic malignant melanoma are present in 3 of 16 lymph nodes. (No evidence of malignancy is seen in block J).

Electronic signature

Verified by:

DIAGNOSIS

Axillary lymph node: METASTATIC MALIGNANT MELANOMA in 3 of 16 nodes.

HIKAA Discrepancy		☒
Dual/Synchronous Primary N/A		☒

[page 2 of 2]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

SUMMARY / KEY WORDS

Lymph node - malignant melanoma, metastatic
Haematopathology resection

Source: NCI Genomic Data Commons file 544fcced-c03d-4d14-8501-18c55905f3f2 (TCGA-EE-A2MJ.E1EB9123-2749-42DA-9981-C9C4C7D72B5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).